Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3815, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3815-01A (Primary Tumor).

Diagnosis

This concerns a slightly differentiated adenocarcinoma of the cecum with histopathological differentiation grade G3, with erosion/ ulceration of the inner surface of the tumor, with significant peritumoral, chronic recurrent concomitant inflammation with an acute ulcerous, abscess-formed inflammation flare, with tumor infiltration of all cecal wall layers up to 0.1 cm underneath the covering serosa (according to the tumor distance to the lateral preparation border), with carcinomatous lymphangitis, with tumor necroses, with tumor infiltration of the base of the appendix, with chronic recurrent appendicitis, with moderately chronic lymphadenitis of the tumor-free lymph nodes (0/20) as well as tumor-free overview slices from the resection margins.

According to the preparation sections at hand, the tumor spread of the cecum corresponds to a tumor stage of pT3, pN0, MX, L1, R0.

No evidence to suggest carcinosis of the blood vessels.

No evidence to suggest serous carcinoma.

Source: NCI Genomic Data Commons file 7f14c2d2-ed6c-401f-bd3e-82c3b68fd82a (TCGA-AA-3815.A3EDDE6C-4FBE-4690-98B2-64CBC817A365.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).